Somatic mutation profile of tumor specimen BA2634D (aliquot aq-BA2634D) from BEATAML1.0 case 2047, project BEATAML1.0-COHORT (Functional Genomic Landscape of Acute Myeloid Leukemia). Sex at birth: male; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, minimal differentiation; Tissue or organ of origin: Bone marrow; Age at diagnosis: 75.0 years (27,388 days).
Specimen BA2634D: Sample type: Recurrent Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Peripheral Blood NOS; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6e08f0af-b1be-4f34-ab9e-7f47a2bca438.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen BA2535D (Solid Tissue Normal), aliquot aq-BA2535D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/7e31648b-9a2a-4b54-9ff2-788547a0b6cb

The open-access MAF lists 25 somatic variants for this specimen: 20 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 17, Silent 3, Nonsense Mutation 2, Frame Shift Del 1, 3'UTR 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.182A>C p.Q61P | Missense Mutation (SNP) | VAF 23/148 reads (16%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.168); catalogued as rs121913240, COSV55498739, COSV55504296, COSV55508574; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PTPN11 | c.1508G>T p.G503V | Missense Mutation (SNP) | VAF 39/300 reads (13%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs397507546, CM086897, CM115675, CM1314033, COSV61004973, COSV61005158, COSV61008174; ClinVar: other / likely pathogenic; called by muse, mutect2, varscan2
- BAK1 | c.577G>A p.V193M | Missense Mutation (SNP) | VAF 41/132 reads (31%) | SIFT tolerated (0.14); PolyPhen benign (0); catalogued as rs1229218232, COSV62349644; called by muse, mutect2, varscan2
- BRINP3 | c.1793G>A p.R598Q | Missense Mutation (SNP) | VAF 64/126 reads (51%) | SIFT deleterious (0.02); PolyPhen benign (0.053); catalogued as rs757438144, COSV100819444, COSV66529448; called by muse, mutect2, varscan2
- CDH19 | c.173C>T p.T58M | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.413); catalogued as rs538411423, COSV50983698; called by muse, mutect2, varscan2
- ETV6 | c.1193T>A p.L398Q | Missense Mutation (SNP) | VAF 43/110 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM1511685, COSV56766205; called by muse, mutect2, varscan2
- FAM168A | c.181A>G p.T61A (on ENST00000064778 / NM_001286050.2; = p.T52A on NM_015159.3) | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT tolerated, low confidence (0.39); PolyPhen benign (0.186); catalogued as rs751717764, COSV50358367; called by muse, mutect2, varscan2
- GABRE | c.542G>A p.G181D | Missense Mutation (SNP) | VAF 21/81 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs75100154; called by muse, mutect2, varscan2
- KMT5C | c.935G>A p.R312H | Missense Mutation (SNP) | VAF 28/82 reads (34%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0); catalogued as rs776285868; called by muse, varscan2
- NOL10 | c.172A>G p.I58V | Missense Mutation (SNP) | VAF 40/93 reads (43%) | SIFT tolerated (0.54); PolyPhen benign (0.001); catalogued as rs777464100; called by muse, mutect2, varscan2
- PRKCSH | c.46G>C p.E16Q | Missense Mutation (SNP) | VAF 75/231 reads (32%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.997); catalogued as COSV52950963; called by muse, varscan2
- RYR2 | c.11428C>T p.R3810* | Nonsense Mutation (SNP) | VAF 33/100 reads (33%) | catalogued as rs1446308525, COSV63689998; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TRIM33 | c.674G>A p.S225N | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT tolerated (0.08); PolyPhen benign (0.237); catalogued as rs939768651; called by muse, mutect2, varscan2
- AMMECR1L | c.531del p.D177Efs*7 | Frame Shift Del (DEL) | VAF 32/99 reads (32%) | called by mutect2, pindel, varscan2
- CPAMD8 | c.3473C>T p.A1158V (on ENST00000651564; = p.A1111V on NM_015692.5) | Missense Mutation (SNP) | VAF 63/151 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.056); called by muse, mutect2, varscan2
- FAM185A | c.17C>A p.S6* | Nonsense Mutation (SNP) | VAF 4/47 reads (9%) | called by muse, mutect2
- GLP2R | c.1424G>C p.G475A | Missense Mutation (SNP) | VAF 65/190 reads (34%) | SIFT tolerated (0.08); PolyPhen benign (0.13); called by muse, mutect2, varscan2
- PDGFRB | c.1247C>T p.P416L | Missense Mutation (SNP) | VAF 13/46 reads (28%) | SIFT deleterious (0.03); PolyPhen benign (0.346); called by muse, mutect2, varscan2
- YWHAB | c.152A>G p.K51R | Missense Mutation (SNP) | VAF 104/144 reads (72%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.734); called by muse, mutect2, varscan2
- ZNF285 | c.412T>C p.W138R | Missense Mutation (SNP) | VAF 59/133 reads (44%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.807); called by muse, mutect2, varscan2
- CANX | c.762A>G p.Q254= | Silent (SNP) | VAF 25/81 reads (31%) | catalogued as rs1259050571; called by muse, mutect2, varscan2
- HYDIN | c.210C>T p.C70= | Silent (SNP) | VAF 51/114 reads (45%) | catalogued as rs775818417; called by muse, mutect2, varscan2
- NT5C1A | c.753G>A p.K251= | Silent (SNP) | VAF 29/48 reads (60%) | catalogued as COSV52496885; called by muse, mutect2, varscan2
- ARL13B | c.*273dup | 3'UTR (INS) | VAF 45/250 reads (18%) | called by mutect2, pindel, varscan2
- SLC25A3 | c.645-84G>A | Intron (SNP) | VAF 90/213 reads (42%) | catalogued as rs748332641; called by muse, mutect2, varscan2
